Gene-level copy-number profile of tumor specimen ALCH-ADWT-TTP1-A from ALCHEMIST case ALCH-ADWT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.0 years (19,348 days).
Specimen ALCH-ADWT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b1a760b0-bd71-4be8-86be-3658b9c2fc46.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADWT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/3d7af37d-2b61-47ee-8fbc-8f87f8d70930

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 12,561; copy number 2: 39,097; copy number 3: 6,816; copy number 4: 308; copy number 5: 71; copy number 9: 1; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:100,150,623–100,154,003, 1 gene: POLR2K.
- chr8:100,158,868–100,185,239, 3 genes (within-gene range 0–2): Y_RNA, AC025647.1, Y_RNA.
- chr9:18,360,597–18,362,220, 1 gene: AL442638.1.
- chr9:21,278,050–23,438,700, 42 genes: IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 74 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,754,301–149,900,798, 18 genes, copy number 5: AC243772.1, FCGR1A, H2BC18, AC243772.2, H3C13, H4C14, H3C14, H2AC18, H2BC19P, H2BC20P, H2AC19, H3C15, H4C15, AC239868.1, H2BC21, H2AC20, H2AC21, BOLA1.
- chr1:154,469,772–155,331,114, 53 genes, copy number 5: SHE, AL162591.2, TDRD10, UBE2Q1, UBE2Q1-AS1, CHRNB2, AL592078.1, ADAR, KCNN3, PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1.
- chr1:248,936,581–248,937,043, 1 gene, copy number 9: RPL23AP25.
- chr8:64,091–79,775, 2 genes, copy number 11: AC144568.1, AC144568.2.

Autosomal genes at a single copy (total copy number 1): 9,728. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
